Surgical pathology report (de-identified scan), TCGA case TCGA-HD-7917, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-HD-7917-01A (Primary Tumor).

[page 1 of 3]
Surg Path Final Report

* Final Report *

Clinical Information (Verified)

Cancer of mouth.

Final Diagnosis (Verified)

Surgical resection of floor of mouth, partial glossectomy with mandibular resection, with frozen section examination:

Infiltrating keratinizing squamous cell carcinoma, tumor measures 2.8 cm x 2.5 cm grossly and extends down within the submucosal tissue 0.5 cm.

Adjacent tonsillar tissue, negative for malignancy.

All surgical margins of excision free.

No lymphovascular invasion is identified.

No perineural invasion is identified.

p16 immunostain will be done and reported in an addendum.

Mandibular bone negative.

Right neck dissection:

Level 1B lymph node dissection:

Two (2) negative lymph nodes.

Negative salivary gland.

Level 1A lymph node dissection:

Two (2) negative nodes.

Right level 2 lymph node dissection:

Six (6) negative nodes.

Right level 3:

Printed by:
Printed on:

Page 1 of 3
(Continued)

[page 2 of 3]
Surg Path Final Report

* Final Report *

Three (3) negative nodes.

Ventral tongue lesion, biopsy:

Superficially invasive keratinizing squamous cell carcinoma, margins of surgical excision free.

Comment: A p16 immunostain will be done on the large squamous cell carcinoma, and an addendum report will follow. This case corresponds to a pathological AJCC classification of: pT2, pN0.

Signature Line

Frozen Section Diagnosis (Verified)

Right lateral tongue, post oral mucosa and post mandible.

FSA1: Superior margin - free.

FSA2 (deep to tumor and lateral) - free.

(SCC on FSA1 and FSA2).

Performing Lab (Verified)

Gross Description (Verified)

"FSA1." All frozen section control tissue is submitted in "FSA1".

"FSA2." All frozen section control tissue is submitted in "FSA2".

Printed by:
Printed on:

Page 2 of 3
(Continued)

[page 3 of 3]
Surg Path Final Report

* Final Report *

"NFSA." The specimen consists of a 6.2 x 4.5 x 1.7 cm portion of right lateral tongue, posterior oral mucosa and portion of mandible. The mandible measures 2.5 x 1 x 0.7 cm and the attached portion of tongue measures 3 x 1.7 x 1.2 cm. The specimen has been inked as follows: medial green, superior blue, lateral orange, inferior yellow, and deep black. Located on the superficial aspect of the specimen is a 2.8 x 2.5 cm gray-white nodular-appearing mass. This comes to within 0.7 cm from the superior margin, 0.4 cm from the lateral margin, 2 cm from the inferior margin, and 0.6 cm from the medial margin. This grossly appears to come within 0.3 cm from the deep margin. The mandible does not grossly appear to be involved with tumor. On sectioning through the soft tissue near the medial margin are two possible lymph nodes measuring 0.8 and 0.5 cm. "A1-A2," mass to include lateral and deep margins; "A3," lymph nodes to include medial margin; "A4," mass medial and deep margins; "A5," inferior and superior margins; "A6-A7," mandible bone margins; "A8," central mandible, representative. Decal "A6-A8".

"Right level 1B." The specimen consists of a 4.5 x 3 x 2.2 cm right submandibular gland with attached fatty tissue. The gland will be inked black. On sectioning, the submandibular gland has a tan lobulated grossly unremarkable appearance. On examination of the surrounding soft tissue, two possible lymph nodes are identified. "B1," possible lymph nodes; "B2-B4," submandibular gland.

"Right level 1A." The specimen consists of a 4 x 3 x 1.5 cm yellow-tan fatty fragment. On examination, 3 possible lymph nodes are identified. These range in size from 0.3 – 0.8 cm. All lymphoid tissue is submitted in "C," representative.

"Ventral tongue lesion." The specimen consists of a 1 x 0.6 x 0.2 cm gray-tan portion of tongue with a centrally located 0.4 cm white-tan dome-shaped area. The specimen is inked black and is serially sectioned. "D," 5p, all.

"Right level 2." The specimen consists of a 5.5 x 3.7 x 1.7 cm yellow-tan fatty fragment. On examination, 7 possible lymph nodes are identified. These range in size from 0.5 – 1.5 cm. All lymphoid tissue is submitted in "E1-E2".

"Right level 3." The specimen consists of a 4.7 x 3 x 1.7 cm fragment of yellow fatty tissue. On examination, 3 possible lymph nodes are identified. These range in size from 0.7 – 1.7 cm. "F1-F2," fragments, representative.

Signature Line

Completed Action List:

Printed by:
Printed on:

Page 3 of 3
(End of Report)

Source: NCI Genomic Data Commons file 8f4a6996-16fc-4b51-8fb6-2d2e6ae29788 (TCGA-HD-7917.3F16361A-C7A7-426C-B9B2-DB0328195604.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).